Somatic mutation profile of tumor specimen ALCH-B34A-TTP1-A (aliquot ALCH-B34A-TTP1-A-2-0-D-A77K-36) from ALCHEMIST case ALCH-B34A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 51.7 years (18,894 days).
Specimen ALCH-B34A-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41e72565-82d1-4b73-acfd-e950794dc07d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B34A-NB1-A (Blood Derived Normal), aliquot ALCH-B34A-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe27140c-bdb5-4e65-904b-7ca4f91e2e56

The open-access MAF lists 423 somatic variants for this specimen: 285 protein-altering or splice-affecting, 85 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 230, Silent 85, Intron 26, Nonsense Mutation 19, Splice Region 12, RNA 11, Frame Shift Del 9, Splice Site 8, 5'UTR 7, 5'Flank 4, 3'UTR 4, Frame Shift Ins 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.163G>T p.G55* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | catalogued as rs1566944812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 46/135 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50272367, COSV50632231; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 52/175 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABAT | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99191024; called by muse, mutect2, varscan2
- ABCA9 | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs747063365; called by muse, mutect2, varscan2
- ADAD1 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.705); catalogued as rs766526962; called by muse, mutect2, varscan2
- ADGRB1 | c.4380G>T p.E1460D | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs868345940; called by muse, mutect2, varscan2
- ADGRG4 | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs1416408798, COSV99795090; called by muse, mutect2, varscan2
- ANK1 | c.2944G>T p.G982W | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55879669, COSV99226734; called by muse, mutect2, varscan2
- ANKRD36 | c.3189G>C p.L1063F | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.991); catalogued as COSV101347496; called by muse, mutect2, varscan2
- APOB | c.9397C>A p.P3133T | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51924392; called by muse, mutect2, varscan2
- AQP12B | c.136G>T p.V46F (on ENST00000621682; = p.V58F on NM_001102467.2) | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV68183699; called by muse, mutect2, varscan2
- ARID2 | c.3364G>T p.V1122F | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.603); catalogued as COSV57617408; called by muse, mutect2, varscan2
- ARRDC2 | c.868G>T p.G290* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as COSV55843429; called by muse, mutect2, varscan2
- ASB5 | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99642192; called by muse, mutect2, varscan2
- ASPM | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 43/340 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as rs1227283442, COSV99659125; called by muse, mutect2, varscan2
- CACNA1B | c.4718C>T p.A1573V | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53156842; called by muse, mutect2, varscan2
- CAPN8 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.669); catalogued as COSV64815498; called by muse, mutect2, varscan2
- CCDC88C | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV101104686; called by muse, mutect2, varscan2
- CD36 | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 118/348 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV59220673; called by muse, mutect2, varscan2
- CD83 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 33/208 reads (16%) | catalogued as rs149141188; called by muse, mutect2, varscan2
- COL1A2 | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 215/929 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51955270; called by muse, mutect2, varscan2
- COL4A5 | c.4342G>T p.G1448C | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM050564, CM1510910; called by muse, mutect2, varscan2
- CPQ | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV55148764; called by muse, mutect2, varscan2
- CSMD1 | c.5174G>T p.R1725L (on ENST00000520002; = p.R1724L on NM_033225.6) | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756028139, COSV59395932; called by muse, mutect2, varscan2
- CSMD2 | c.4500T>A p.H1500Q | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53940144; called by muse, mutect2, varscan2
- CSMD3 | c.10577G>T p.G3526V (on ENST00000297405 / NM_001363185.1; = p.G3357V on NM_052900.3) | Missense Mutation (SNP) | VAF 80/431 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52240954; called by muse, mutect2, varscan2
- CSMD3 | c.10576G>T p.G3526W (on ENST00000297405 / NM_001363185.1; = p.G3357W on NM_052900.3) | Missense Mutation (SNP) | VAF 78/441 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52158087; called by muse, mutect2, varscan2
- CTNNA2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 101/439 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as rs1396563178; called by muse, mutect2, varscan2
- CTRB2 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs138352937; called by muse, mutect2, varscan2
- CUL1 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV100296952; called by muse, mutect2, varscan2
- DCAF12L2 | c.932G>T p.C311F | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100758472; called by muse, mutect2, varscan2
- DCAF17 | c.322G>T p.G108* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as rs1381170912; called by muse, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs754135731; called by mutect2, varscan2*
- DIPK1C | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV100679789; called by muse, mutect2, varscan2
- DSC3 | c.1227C>A p.D409E | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV64573712; called by muse, mutect2, varscan2
- DSPP | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 50/312 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.028); catalogued as COSV104390358, COSV99216729; called by muse, mutect2, varscan2
- DTX4 | c.1356G>T p.M452I | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99915095; called by muse, mutect2, varscan2
- EIF2AK3 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs1201810520; called by muse, mutect2, varscan2
- EIF3F | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as rs1432467824; called by muse, mutect2, varscan2
- ETV1 | c.954A>T p.Q318H | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV99623619; called by muse, mutect2, varscan2
- FAM47B | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV61452324; called by muse, mutect2, varscan2
- FANCM | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57508747; called by muse, mutect2, varscan2
- FBN1 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM130604, CS098589; called by muse, mutect2, varscan2
- FBXO46 | c.1252G>T p.G418W | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100480396, COSV58349290; called by muse, mutect2, varscan2
- H2BW1 | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV99475091; called by muse, mutect2, varscan2
- HCRTR2 | c.1003C>A p.H335N | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100904103; called by muse, mutect2, varscan2
- HDGF | c.350A>T p.E117V | Missense Mutation (SNP) | VAF 66/330 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as COSV100625765; called by muse, mutect2, varscan2
- IGKV3D-20 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322332974; called by muse, mutect2
- IGSF3 | c.1747C>T p.R583W (on ENST00000369486 / NM_001007237.3; = p.R603W on NM_001542.4) | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs200735353, COSV59592548; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNC1 | c.278T>A p.F93Y | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV56393767; called by muse, mutect2, varscan2
- KCNH5 | c.1086G>T p.W362C | Missense Mutation (SNP) | VAF 106/467 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59763492; called by muse, mutect2, varscan2
- KCNT2 | c.1038G>T p.R346S | Missense Mutation (SNP) | VAF 71/435 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV54062974; called by muse, mutect2, varscan2
- LARP7 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1317670018; called by muse, mutect2, varscan2
- LPA | c.3076G>T p.V1026F | Missense Mutation (SNP) | VAF 83/403 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs759100515, COSV60295959, COSV60307886, COSV60309914; called by muse, mutect2, varscan2
- MAP3K19 | c.1210C>G p.P404A | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs967139450, COSV100208277; called by muse, mutect2, varscan2
- MED27 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1430956704, COSV52605948; called by muse, mutect2, varscan2
- MUC16 | c.1178C>A p.P393Q | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); catalogued as COSV67449366; called by muse, mutect2, varscan2
- NDST3 | c.2133T>A p.H711Q | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768992581; called by muse, mutect2
- NIT2 | c.126+1del | Frame Shift Del (DEL) | VAF 22/168 reads (13%) | catalogued as COSV101237104; called by mutect2, pindel, varscan2
- NPAS3 | c.364C>A p.P122T (on ENST00000356141 / NM_001164749.2; = p.P92T on NM_022123.3) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV100390590; called by muse, mutect2, varscan2
- NPHS1 | c.3604G>T p.D1202Y | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV62286822; called by muse, mutect2, varscan2
- OR11G2 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs199984570; called by muse, mutect2, varscan2
- OR4C46 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 77/484 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as rs1173698365; called by muse, mutect2, varscan2
- OR4C6 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as COSV58606723; called by muse, mutect2, varscan2
- OR4N5 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100374074, COSV61321295; called by muse, mutect2, varscan2
- OR4N5 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 69/352 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs865893663, COSV61320296; called by muse, mutect2, varscan2
- OR51F1 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV58579678; called by muse, mutect2, varscan2
- OR52E6 | c.796G>C p.G266R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100259310; called by muse, mutect2, varscan2
- OR5AR1 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs369265341; called by muse, mutect2, varscan2
- PCDH15 | c.4604C>A p.P1535Q | Missense Mutation (SNP) | VAF 77/335 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.995); catalogued as rs1374646895, COSV64690403; called by muse, mutect2, varscan2
- PCDHA13 | c.1320C>A p.S440R | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.338); catalogued as rs781923113, COSV56507457; called by muse, mutect2, varscan2
- PROS1 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV62399773; called by muse, mutect2, varscan2
- PTBP3 | c.118+7A>T | Splice Region (SNP) | VAF 44/198 reads (22%) | catalogued as rs1275171468; called by muse, varscan2
- PTCRA | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757865292; called by muse, mutect2, varscan2
- RB1 | c.1345G>C p.G449R | Missense Mutation (SNP) | VAF 159/502 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CS071257, COSV57306967; called by muse, mutect2, varscan2
- RGS21 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV69881483; called by muse, mutect2
- RRP15 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV65118530; called by muse, mutect2
- SELE | c.182C>A p.S61Y | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs770105052, COSV60973751; called by muse, mutect2, varscan2
- SLAMF9 | c.861C>A p.S287R | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV63636493; called by mutect2, varscan2
- SLC13A2 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs782774839; called by muse, mutect2
- SLC22A5 | c.1505C>T p.T502I | Missense Mutation (SNP) | VAF 81/366 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs750468729; called by muse, mutect2, varscan2
- SLC35F3 | c.182C>T p.A61V (on ENST00000366617 / NM_001300845.1; = p.A130V on NM_173508.4) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV64019863; called by muse, mutect2
- SLC4A10 | c.948+1G>T p.X316_splice | Splice Site (SNP) | VAF 59/284 reads (21%) | catalogued as rs1225316385; called by muse, mutect2, varscan2
- SLC9A4 | c.1200C>T p.S400= | Splice Region (SNP) | VAF 47/184 reads (26%) | catalogued as rs531246466; called by muse, mutect2, varscan2
- SPATA18 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV54651036; called by muse, mutect2, varscan2
- STRIP2 | c.757G>T p.V253F | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV50808569; called by muse, mutect2, varscan2
- SV2C | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 81/358 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV59224720; called by muse, mutect2, varscan2
- TMEM132C | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV70657737; called by muse, mutect2, varscan2
- TMEM132E | c.2708G>A p.G903D (on ENST00000321639; = p.G993D on NM_001304438.2) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs1199065700; called by muse, mutect2
- TNFRSF8 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs193921033, COSV55799349; called by muse, mutect2
- TNR | c.971C>A p.S324* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs868644777; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1408C>A p.L470M | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.798); catalogued as COSV50550453; called by muse, mutect2, varscan2
- TRIML2 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100456148; called by muse, mutect2, varscan2
- TRPS1 | c.2708A>T p.K903M (on ENST00000220888 / NM_001330599.2; = p.K916M on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/799 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55234210; called by muse, mutect2, varscan2
- VWA3A | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs376140454; called by muse, varscan2
- WDR36 | c.1572G>T p.Q524H | Missense Mutation (SNP) | VAF 102/492 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72605063; called by muse, mutect2, varscan2
- XIRP2 | c.7570C>A p.P2524T (on ENST00000628543; = p.P2699T on NM_152381.6) | Missense Mutation (SNP) | VAF 66/377 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99743376; called by muse, mutect2, varscan2
- ABCA13 | c.1820A>G p.N607S | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCC2 | c.3539A>T p.Q1180L | Missense Mutation (SNP) | VAF 78/267 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ABCC3 | c.1272_1273delinsT p.F426Sfs*23 | Frame Shift Del (DEL) | VAF 30/192 reads (16%) | called by pindel, varscan2*
- AC013489.1 | c.996G>A p.W332* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- ACCS | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- ADARB2 | c.426C>A p.Y142* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- ADCY2 | c.2776C>A p.L926I | Missense Mutation (SNP) | VAF 287/720 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ADGRA1 | c.54C>A p.H18Q | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- AHR | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- AKAP12 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- AKR1D1 | c.419G>T p.W140L | Missense Mutation (SNP) | VAF 103/305 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AL121899.2 | c.1625C>A p.T542N | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- AMBN | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMER3 | c.1426C>A p.P476T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ANK2 | c.2868C>A p.N956K | Missense Mutation (SNP) | VAF 95/546 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.5507C>A p.S1836Y | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ANKRD30B | c.820+1G>T p.X274_splice | Splice Site (SNP) | VAF 40/273 reads (15%) | called by muse, mutect2, varscan2
- APOB | c.7543A>T p.T2515S | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ARMH4 | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- ASB5 | c.141C>A p.N47K | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASL | c.655+5G>T | Splice Region (SNP) | VAF 98/237 reads (41%) | called by muse, mutect2, varscan2
- ASXL3 | c.3733A>T p.I1245L | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- AXDND1 | c.2798+1G>C p.X933_splice | Splice Site (SNP) | VAF 31/132 reads (23%) | called by muse, mutect2, varscan2
- BBS12 | c.1141G>T p.V381L | Missense Mutation (SNP) | VAF 68/389 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BPTF | c.2554C>T p.H852Y | Missense Mutation (SNP) | VAF 53/349 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, varscan2
- C14orf28 | c.488G>C p.R163P | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- C1RL | c.629G>T p.C210F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- C21orf58 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2
- CA4 | c.609C>A p.S203R | Missense Mutation (SNP) | VAF 74/293 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1C | c.5693G>T p.G1898V (on ENST00000399634 / NM_001167625.1; = p.G1827V on NM_000719.7) | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CASP12 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CCDC168 | c.14318dup p.N4773Kfs*20 | Frame Shift Ins (INS) | VAF 152/428 reads (36%) | called by mutect2, pindel, varscan2
- CCDC175 | c.1458T>A p.N486K | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CCDC185 | c.658_664del p.S220Pfs*22 | Frame Shift Del (DEL) | VAF 22/113 reads (19%) | called by mutect2, pindel, varscan2
- CDC40 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC42BPG | c.3832G>A p.E1278K | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CNDP2 | c.701dup p.S235Lfs*4 | Frame Shift Ins (INS) | VAF 50/146 reads (34%) | called by mutect2, pindel, varscan2
- COPA | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 54/327 reads (17%) | called by muse, mutect2, varscan2
- CRISP2 | c.492C>A p.Y164* | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- CSMD3 | c.4345C>T p.P1449S (on ENST00000297405 / NM_001363185.1; = p.P1345S on NM_052900.3) | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CYFIP2 | c.2055G>A p.M685I (on ENST00000616178 / NM_001291722.2; = p.M660I on NM_014376.4) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- CYP11B1 | c.1211G>C p.R404P | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CYP2C9 | c.1057C>G p.H353D | Missense Mutation (SNP) | VAF 76/262 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP46A1 | c.908-2A>T p.X303_splice | Splice Site (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- DAB1 | c.1399C>G p.P467A (on ENST00000371231; = p.P434A on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- DCLK2 | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- DDX31 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DEFB113 | c.238C>G p.H80D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX34 | c.1031del p.P344Rfs*20 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | called by mutect2, pindel, varscan2
- DIPK2B | c.292C>G p.P98A | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DMXL2 | c.2909T>A p.L970H | Missense Mutation (SNP) | VAF 78/303 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH6 | c.5267G>T p.G1756V | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH8 | c.165G>T p.R55S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAJC10 | c.2188G>C p.A730P | Missense Mutation (SNP) | VAF 65/368 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DPF3 | c.1132G>T p.A378S | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPYS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSP | c.1574+3_1574+15del p.X525_splice | Splice Site (DEL) | VAF 31/206 reads (15%) | called by mutect2, pindel, varscan2
- E2F8 | c.211A>T p.S71C | Missense Mutation (SNP) | VAF 77/379 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ECEL1 | c.1527G>T p.M509I | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- EIF2B4 | c.460C>T p.L154F (on ENST00000347454 / NM_001034116.2; = p.L153F on NM_015636.3) | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2
- EIF4G3 | c.770T>A p.V257E | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EML5 | c.3857T>C p.I1286T | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPPK1 | c.3848A>T p.Q1283L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ESRRA | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ESRRG | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- EVI5L | c.248A>T p.E83V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- EYS | c.3985G>A p.V1329I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FBXW7 | c.719T>G p.M240R (on ENST00000281708 / NM_001349798.2; = p.M160R on NM_018315.5) | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMO1 | c.902C>A p.P301Q | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FNDC1 | c.3322C>T p.P1108S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOLH1 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FOXG1 | c.916C>A p.L306I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- FSIP2 | c.15721C>A p.H5241N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- FTCDNL1 | c.137C>G p.S46* | Nonsense Mutation (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- GABRQ | c.1325C>G p.A442G | Missense Mutation (SNP) | VAF 148/216 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- GML | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- GPR158 | c.1012A>T p.M338L | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR26 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GRM3 | c.2639G>C p.*880Sext*2 | Nonstop Mutation (SNP) | VAF 96/253 reads (38%) | called by muse, mutect2, varscan2
- HECTD3 | c.845G>T p.R282L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- HMCN2 | c.15138C>A p.S5046R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- HORMAD1 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HSPA12B | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IFNA5 | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHG3 | c.961T>C p.Y321H | Missense Mutation (SNP) | VAF 78/320 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IGHV3-38 | c.257C>G p.T86S | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- IGSF1 | c.1647A>G p.R549= | Splice Region (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2, varscan2
- INSYN2A | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- INVS | c.2665G>T p.V889L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IPO13 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- IQCG | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- KALRN | c.1873C>A p.R625S | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNT1 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- KIF12 | c.1814G>C p.R605T (on ENST00000640217; = p.R467T on NM_138424.1) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); called by muse, varscan2
- KLHL21 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- KRT77 | c.942C>G p.I314M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KRTAP5-3 | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA2 | c.7896A>G p.R2632= | Splice Region (SNP) | VAF 58/352 reads (16%) | called by muse, mutect2, varscan2
- LETM1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- LGALS9 | c.686C>T p.T229I (on ENST00000395473 / NM_009587.3; = p.T197I on NM_002308.4) | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- LPIN2 | c.192+7G>T | Splice Region (SNP) | VAF 62/392 reads (16%) | called by muse, mutect2, varscan2
- LRATD2 | c.842dup p.D282Rfs*128 | Frame Shift Ins (INS) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- MAGEB4 | c.777G>T p.Q259H | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAGEL2 | c.956T>G p.M319R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- MAP1S | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- MTCL1 | c.5210G>T p.G1737V (on ENST00000306329 / NM_001378206.1; = p.G1418V on NM_015210.4) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- MTUS2 | c.169G>T p.G57* | Nonsense Mutation (SNP) | VAF 92/196 reads (47%) | called by muse, mutect2, varscan2
- MYCBPAP | c.2512G>C p.D838H | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MYH7 | c.4518G>A p.Q1506= | Splice Region (SNP) | VAF 31/173 reads (18%) | called by muse, mutect2, varscan2
- MYNN | c.267-1G>A p.X89_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- MYO15B | c.6920G>A p.S2307N | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2
- MYO1G | c.2706C>A p.D902E | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYT1L | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.354); called by muse, varscan2
- NELL1 | c.490C>A p.H164N | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- NELL1 | c.2392G>T p.V798F | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- NLGN1 | c.380C>A p.P127Q | Missense Mutation (SNP) | VAF 49/362 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NLRP8 | c.1492G>T p.G498C | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- OLFM4 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2M5 | c.445T>A p.W149R | Missense Mutation (SNP) | VAF 58/391 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4P4 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR5AP2 | c.36_37dup p.T13Kfs*4 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by pindel, varscan2
- OR5W2 | c.345del p.S116Qfs*2 | Frame Shift Del (DEL) | VAF 33/222 reads (15%) | called by mutect2, pindel, varscan2
- OR6P1 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 44/212 reads (21%) | called by muse, mutect2, varscan2
- PALD1 | c.1672C>A p.H558N | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PCK1 | c.735C>A p.C245* | Nonsense Mutation (SNP) | VAF 34/173 reads (20%) | called by muse, mutect2, varscan2
- PDCD1 | c.766G>T p.G256* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- PDCD1 | c.457A>T p.T153S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PDZRN3 | c.1001A>T p.Q334L | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PHKA1 | c.423C>A p.Y141* | Nonsense Mutation (SNP) | VAF 124/433 reads (29%) | called by muse, mutect2, varscan2
- PIEZO2 | c.6636G>T p.G2212= | Splice Region (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- PKDCC | c.472C>G p.P158A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLXND1 | c.292del p.V98Cfs*40 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | called by mutect2, pindel, varscan2
- POLD3 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- PPP1R1A | c.183+1G>T p.X61_splice | Splice Site (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- PRAMEF15 | c.1426T>C p.Y476H | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.179); called by muse, varscan2
- PRDM6 | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PREX2 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 55/414 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRPF40A | c.614G>T p.W205L | Missense Mutation (SNP) | VAF 49/335 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PRR30 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PTGFR | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PTPRU | c.2642A>T p.Q881L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PUM2 | c.2959C>T p.H987Y | Missense Mutation (SNP) | VAF 52/373 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RARA | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated, low confidence (0.59); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- REG1B | c.417C>A p.S139R | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RPS6KC1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 59/332 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RRBP1 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.079); called by muse, varscan2
- RYR2 | c.10839-2A>T p.X3613_splice | Splice Site (SNP) | VAF 52/218 reads (24%) | called by muse, mutect2, varscan2
- SAA2 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SALL3 | c.392C>A p.A131D | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINH1 | c.384del p.W128* | Frame Shift Del (DEL) | VAF 37/196 reads (19%) | called by mutect2, pindel, varscan2
- SIGLEC5 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- SLC9A5 | c.2581C>A p.Q861K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLFN14 | c.1557G>T p.Q519H | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- SON | c.6768+6T>C | Splice Region (SNP) | VAF 152/403 reads (38%) | called by muse, mutect2, varscan2
- SORCS3 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SOX11 | c.1111C>G p.Q371E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SRCIN1 | c.2829+8G>T | Splice Region (SNP) | VAF 47/186 reads (25%) | called by muse, mutect2, varscan2
- SRCIN1 | c.2829+7G>T | Splice Region (SNP) | VAF 48/186 reads (26%) | called by muse, mutect2, varscan2
- ST8SIA6 | c.1086C>A p.N362K | Missense Mutation (SNP) | VAF 91/516 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SULF2 | c.1410del p.K471Sfs*2 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel
- SV2C | c.1246G>T p.G416* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- SYNE2 | c.20158G>T p.V6720L | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- TAF3 | c.2332del p.V778Sfs*71 | Frame Shift Del (DEL) | VAF 59/311 reads (19%) | called by mutect2, pindel, varscan2
- TENM3 | c.2933C>G p.S978C | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- THPO | c.1375C>A p.Q459K (on ENST00000649095 / NM_001290003.1; = p.Q319K on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); called by muse, mutect2
- TMEM129 | c.487_528del p.R163_T176del | In Frame Del (DEL) | VAF 33/314 reads (11%) | called by mutect2, pindel
- TMEM132C | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- TMEM132C | c.2829C>G p.I943M | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM161B | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TMEM215 | c.693C>G p.H231Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPP2 | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TRAF2 | c.462C>G p.H154Q | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAFD1 | c.550A>T p.R184W | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- TRIM51GP | c.507G>A p.K169= | Splice Region (SNP) | VAF 35/177 reads (20%) | called by muse, mutect2, varscan2
- TRIM64C | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 73/450 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPS1 | c.1583G>T p.C528F (on ENST00000220888 / NM_001330599.2; = p.C541F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UBA6 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBR2 | c.156G>T p.R52S | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBR4 | c.8227T>G p.S2743A | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- UPK1B | c.192T>A p.F64L | Missense Mutation (SNP) | VAF 120/604 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- URB1 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VGLL3 | c.920G>T p.S307I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VNN3 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- VPS8 | c.775G>T p.A259S (on ENST00000625842 / NM_001349294.1; = p.A257S on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZBTB8B | c.114C>G p.H38Q | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- ZNF560 | c.1699G>T p.A567S | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF658 | c.296G>T p.W99L | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABHD10 | c.75C>T p.F25= | Silent (SNP) | VAF 27/161 reads (17%) | catalogued as COSV56325844; called by muse, mutect2, varscan2
- ACTRT1 | c.69A>T p.A23= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV100947482; called by muse, mutect2, varscan2
- ADARB2 | c.427C>A p.R143= | Silent (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- ALG1 | c.165G>T p.S55= | Silent (SNP) | VAF 43/146 reads (29%) | called by muse, mutect2, varscan2
- AMOTL1 | c.1704G>T p.R568= | Silent (SNP) | VAF 47/299 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.204G>A p.L68= | Silent (SNP) | VAF 29/264 reads (11%) | called by muse, mutect2, varscan2
- ARHGDIG | c.582C>A p.G194= | Silent (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- ARSI | c.1503G>A p.P501= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs756540774; called by muse, mutect2, varscan2
- ASTL | c.595C>A p.R199= | Silent (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- ATP4A | c.1818C>A p.P606= | Silent (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- BRPF3 | c.2820A>G p.L940= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as rs377077625; called by muse, mutect2, varscan2
- CACNA1I | c.36A>T p.A12= | Silent (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- CCDC168 | c.2250T>C p.N750= | Silent (SNP) | VAF 31/187 reads (17%) | called by muse, mutect2, varscan2
- CCDC74B | c.606G>A p.Q202= | Silent (SNP) | VAF 59/266 reads (22%) | catalogued as COSV60102279; called by muse, mutect2, varscan2
- CDH16 | c.2133G>T p.T711= | Silent (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- CDH17 | c.2328A>G p.A776= | Silent (SNP) | VAF 43/290 reads (15%) | called by muse, mutect2, varscan2
- CES1 | c.189G>C p.L63= | Silent (SNP) | VAF 91/331 reads (27%) | catalogued as COSV100828684; called by muse, mutect2, varscan2
- CFAP47 | c.7956G>A p.Q2652= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as rs1169922159; called by muse, mutect2, varscan2
- CFC1 | c.153C>T p.L51= | Silent (SNP) | VAF 41/398 reads (10%) | called by muse, varscan2
- COQ8B | c.753C>T p.V251= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- CPSF2 | c.1023C>T p.L341= | Silent (SNP) | VAF 68/368 reads (18%) | called by muse, mutect2, varscan2
- CSMD2 | c.708G>T p.L236= | Silent (SNP) | VAF 45/314 reads (14%) | catalogued as rs769999757; called by muse, mutect2, varscan2
- CYP2A7 | c.621A>T p.G207= | Silent (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- DACH2 | c.1797C>A p.A599= | Silent (SNP) | VAF 59/265 reads (22%) | called by muse, mutect2, varscan2
- DLAT | c.678C>T p.L226= | Silent (SNP) | VAF 81/407 reads (20%) | called by muse, mutect2, varscan2
- DLST | c.306G>C p.V102= | Silent (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- DOCK2 | c.1725G>T p.V575= | Silent (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.7821C>T p.S2607= | Silent (SNP) | VAF 52/240 reads (22%) | catalogued as rs375547282; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FSIP1 | c.12A>T p.I4= | Silent (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- FYN | c.1032T>C p.Y344= | Silent (SNP) | VAF 16/104 reads (15%) | called by muse, varscan2
- GJA5 | c.268C>T p.L90= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs781832760; called by muse, mutect2, varscan2
- GNRHR | c.432G>T p.T144= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV56934799; called by muse, mutect2, varscan2
- HOMER3 | c.1085G>A p.*362= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- HYDIN | c.10473C>G p.P3491= | Silent (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- IGLV6-57 | c.195C>A p.T65= | Silent (SNP) | VAF 80/284 reads (28%) | called by muse, mutect2, varscan2
- IKZF1 | c.1254C>T p.I418= | Silent (SNP) | VAF 54/193 reads (28%) | called by muse, mutect2, varscan2
- ITGAX | c.2622C>A p.A874= | Silent (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- JAM2 | c.558C>T p.T186= | Silent (SNP) | VAF 62/467 reads (13%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2292A>G p.L764= (on ENST00000286628 / NM_001161352.2; = p.L706= on NM_002247.4) | Silent (SNP) | VAF 125/1148 reads (11%) | called by muse, mutect2, varscan2
- KLK9 | c.234C>G p.L78= | Silent (SNP) | VAF 14/19 reads (74%) | catalogued as COSV51592374; called by muse, varscan2
- MAGEC3 | c.1005C>A p.L335= | Silent (SNP) | VAF 46/199 reads (23%) | catalogued as COSV68924498; called by muse, mutect2, varscan2
- MAP7D1 | c.1284G>A p.K428= | Silent (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- MERTK | c.765G>A p.T255= | Silent (SNP) | VAF 37/170 reads (22%) | catalogued as rs368133234; called by muse, mutect2, varscan2
- MFSD1 | c.1014A>G p.V338= | Silent (SNP) | VAF 29/167 reads (17%) | called by muse, mutect2, varscan2
- MOXD1 | c.1452A>T p.P484= | Silent (SNP) | VAF 33/218 reads (15%) | called by muse, mutect2, varscan2
- MPPED2 | c.732G>T p.R244= | Silent (SNP) | VAF 76/407 reads (19%) | catalogued as COSV63901199; called by muse, mutect2, varscan2
- MYOCD | c.1275C>T p.V425= | Silent (SNP) | VAF 14/157 reads (9%) | catalogued as rs1467810705; called by muse, mutect2
- NCF1 | c.645T>C p.S215= | Silent (SNP) | VAF 113/342 reads (33%) | called by muse, mutect2, varscan2
- NDST4 | c.1029C>A p.T343= | Silent (SNP) | VAF 29/199 reads (15%) | called by muse, mutect2, varscan2
- NDUFB1 | c.153C>T p.P51= | Silent (SNP) | VAF 93/503 reads (18%) | called by muse, mutect2, varscan2
- NFASC | c.360C>A p.A120= (on ENST00000339876 / NM_001378329.1; = p.A114= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- NLGN1 | c.381A>G p.P127= | Silent (SNP) | VAF 51/360 reads (14%) | catalogued as rs1560038329; called by muse, mutect2, varscan2
- NPAS4 | c.759G>T p.L253= | Silent (SNP) | VAF 51/293 reads (17%) | called by muse, mutect2, varscan2
- NPHS1 | c.18G>T p.T6= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as rs370650840; called by muse, mutect2, varscan2
- OR10A5 | c.162C>T p.P54= | Silent (SNP) | VAF 88/587 reads (15%) | called by muse, mutect2, varscan2
- OR10A5 | c.894G>A p.V298= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV55053273; called by muse, mutect2
- OR6B2 | c.738C>A p.T246= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as COSV53156979, COSV99401758; called by muse, mutect2, varscan2
- OR9Q2 | c.480G>C p.T160= | Silent (SNP) | VAF 69/381 reads (18%) | catalogued as rs773474840, COSV61111345; called by muse, mutect2, varscan2
- PM20D2 | c.297G>A p.P99= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs747131173; called by muse, mutect2, varscan2
- POM121L12 | c.69G>T p.L23= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV101374901; called by muse, mutect2, varscan2
- PXDNL | c.3012C>A p.I1004= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs1370331286, COSV62479760; called by muse, mutect2, varscan2
- RAMP3 | c.117G>T p.L39= | Silent (SNP) | VAF 61/254 reads (24%) | catalogued as rs373191529; called by muse, mutect2, varscan2
- RDH8 | c.585G>A p.Q195= (on ENST00000651512; = p.Q175= on NM_015725.4) | Silent (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- ROBO1 | c.2046C>T p.N682= | Silent (SNP) | VAF 67/304 reads (22%) | called by muse, mutect2, varscan2
- SALL3 | c.393C>G p.A131= | Silent (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- SCN7A | c.3801C>T p.A1267= | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as rs573169902, COSV69274603; called by muse, mutect2, varscan2
- SIGLEC10 | c.1732C>A p.R578= | Silent (SNP) | VAF 61/167 reads (37%) | called by muse, mutect2, varscan2
- SLC22A15 | c.1125A>C p.L375= | Silent (SNP) | VAF 39/250 reads (16%) | called by muse, mutect2, varscan2
- SOST | c.519C>T p.F173= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as rs1295550294; called by muse, mutect2, varscan2
- SPATA31A6 | c.210G>C p.R70= | Silent (SNP) | VAF 65/422 reads (15%) | called by muse, mutect2, varscan2
- SPOCK3 | c.414C>A p.T138= | Silent (SNP) | VAF 47/285 reads (16%) | called by muse, mutect2, varscan2
- TAS2R38 | c.936G>T p.L312= | Silent (SNP) | VAF 64/164 reads (39%) | catalogued as rs1000912185, COSV71886126; called by muse, mutect2, varscan2
- TGM1 | c.1569C>T p.I523= | Silent (SNP) | VAF 36/278 reads (13%) | catalogued as rs750955048, COSV52864938; ClinVar: likely benign; called by muse, mutect2
- TGM7 | c.1500C>A p.P500= | Silent (SNP) | VAF 50/169 reads (30%) | called by muse, mutect2, varscan2
- TLR8 | c.603A>C p.T201= (on ENST00000218032 / NM_138636.5; = p.T219= on NM_016610.4) | Silent (SNP) | VAF 30/243 reads (12%) | called by muse, mutect2, varscan2
- TNIK | c.2070G>A p.G690= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as COSV52689908, COSV99454895; called by muse, mutect2, varscan2
- TNNT2 | c.342G>T p.A114= | Silent (SNP) | VAF 60/306 reads (20%) | catalogued as COSV99372072; called by muse, mutect2, varscan2
- TPO | c.897G>A p.G299= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- TRAPPC8 | c.252C>T p.A84= | Silent (SNP) | VAF 64/196 reads (33%) | called by muse, mutect2, varscan2
- TRIM58 | c.561G>A p.E187= | Silent (SNP) | VAF 49/206 reads (24%) | catalogued as COSV100825015; called by muse, mutect2, varscan2
- TTC37 | c.2940C>T p.A980= | Silent (SNP) | VAF 76/351 reads (22%) | called by muse, mutect2, varscan2
- UNC80 | c.54C>A p.I18= | Silent (SNP) | VAF 56/263 reads (21%) | called by muse, mutect2, varscan2
- URB2 | c.3987G>T p.L1329= | Silent (SNP) | VAF 57/261 reads (22%) | called by muse, mutect2, varscan2
- VPS13D | c.1095G>C p.L365= | Silent (SNP) | VAF 22/120 reads (18%) | called by muse, mutect2, varscan2
- XKR7 | c.1419C>G p.P473= | Silent (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- ABCB5 | c.*35C>A | 3'UTR (SNP) | VAF 44/288 reads (15%) | called by muse, mutect2, varscan2
- ACAD9 | c.633+726C>T | Intron (SNP) | VAF 21/145 reads (14%) | catalogued as rs1306830539; called by muse, mutect2, varscan2
- ACKR1 | c.-1C>A | 5'UTR (SNP) | VAF 37/166 reads (22%) | called by muse, mutect2, varscan2
- AGBL4 | c.34+28487G>T | Intron (SNP) | VAF 43/208 reads (21%) | called by muse, mutect2, varscan2
- AK7 | c.2134-318A>T | Intron (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847212 G>T | 5'Flank (SNP) | VAF 81/328 reads (25%) | called by muse, mutect2, varscan2
- AP002884.2 | c.314+30305C>T | Intron (SNP) | VAF 28/151 reads (19%) | catalogued as rs763479819; called by muse, mutect2, varscan2
- AP4B1 | c.1302+33G>T | Intron (SNP) | VAF 33/214 reads (15%) | called by muse, mutect2, varscan2
- ARMH4 | c.1831+15047T>A | Intron (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- AZIN1 | chr8:102864446 G>T | 5'Flank (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- BMP7 | c.611+2370G>T | Intron (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2, varscan2
- C8orf44-SGK3 | c.-121-26076C>T | Intron (SNP) | VAF 50/385 reads (13%) | called by muse, mutect2, varscan2
- CD247 | c.336+481C>G | Intron (SNP) | VAF 98/539 reads (18%) | called by muse, varscan2
- CD300LD | c.40+103G>T | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- CD59 | c.68-21T>G | Intron (SNP) | VAF 63/388 reads (16%) | called by muse, mutect2, varscan2
- CDH4 | c.170-24444C>T | Intron (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2
- CEP43 | c.*183G>T | 3'UTR (SNP) | VAF 28/185 reads (15%) | called by muse, mutect2, varscan2
- CHD8 | c.5051+466G>T | Intron (SNP) | VAF 30/180 reads (17%) | called by muse, mutect2, varscan2
- CHI3L1 | c.1012-57del | Intron (DEL) | VAF 24/125 reads (19%) | called by mutect2, pindel, varscan2
- DCHS2 | n.8352dup | RNA (INS) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- DDX1 | chr2:15591863 C>T | 5'Flank (SNP) | VAF 10/37 reads (27%) | catalogued as rs962106354; called by muse, mutect2
- DNAJA1 | c.*7A>T | 3'UTR (SNP) | VAF 49/184 reads (27%) | called by muse, mutect2, varscan2
- GRIK2 | c.2563-4343G>T | Intron (SNP) | VAF 28/219 reads (13%) | catalogued as rs1562149133, COSV59711599; called by muse, mutect2, varscan2
- HDGF | c.716+9G>A | Intron (SNP) | VAF 30/137 reads (22%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.749C>A | RNA (SNP) | VAF 41/198 reads (21%) | called by muse, mutect2, varscan2
- IGHV1-12 | n.3G>A | RNA (SNP) | VAF 58/328 reads (18%) | called by muse, mutect2, varscan2
- LGI1 | c.674-27G>A | Intron (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- LRP1B | c.13247+909T>C | Intron (SNP) | VAF 62/396 reads (16%) | called by muse, mutect2, varscan2
- MIR154 | n.25G>T | RNA (SNP) | VAF 57/276 reads (21%) | called by muse, mutect2, varscan2
- MIR548I4 | n.31C>A | RNA (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- MTR | c.3205-9G>T | Intron (SNP) | VAF 54/294 reads (18%) | called by muse, mutect2, varscan2
- NKD1 | c.193-1259G>A | Intron (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1343C>T | RNA (SNP) | VAF 44/174 reads (25%) | catalogued as rs758012403; called by muse, mutect2, varscan2
- NXF3 | c.-12G>A | 5'UTR (SNP) | VAF 34/126 reads (27%) | called by muse, mutect2, varscan2
- OR5P1P | n.446G>T | RNA (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- OTX1 | c.-22G>T | 5'UTR (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- PML | c.1710+19C>T | Intron (SNP) | VAF 47/178 reads (26%) | called by muse, mutect2, varscan2
- POU3F4 | c.-6C>A | 5'UTR (SNP) | VAF 54/206 reads (26%) | called by mutect2, varscan2
- RPL9 | c.47-11del | Intron (DEL) | VAF 76/482 reads (16%) | called by mutect2, pindel, varscan2
- RPS8 | c.-21C>G | 5'UTR (SNP) | VAF 33/161 reads (20%) | catalogued as COSV100785475; called by muse, mutect2, varscan2
- SAMD13 | c.226-4680T>C | Intron (SNP) | VAF 40/225 reads (18%) | called by muse, mutect2, varscan2
- SERTAD4 | c.-18+765C>T | Intron (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- SHISA9 | c.563+5914C>A | Intron (SNP) | VAF 54/204 reads (26%) | called by muse, mutect2, varscan2
- SHOC1 | chr9:111786006 A>T | 5'Flank (SNP) | VAF 14/110 reads (13%) | catalogued as rs1271615399; called by muse, mutect2, varscan2
- SNORD113-7 | n.68T>C | RNA (SNP) | VAF 27/131 reads (21%) | called by muse, mutect2, varscan2
- SORBS1 | c.2129-1173C>T | Intron (SNP) | VAF 45/226 reads (20%) | called by muse, mutect2, varscan2
- SPATA31D5P | n.586C>T | RNA (SNP) | VAF 94/383 reads (25%) | called by muse, mutect2, varscan2
- SPATA8 | n.910G>T | RNA (SNP) | VAF 41/191 reads (21%) | called by muse, mutect2, varscan2
- SSX9P | n.312C>T | RNA (SNP) | VAF 46/231 reads (20%) | called by muse, mutect2, varscan2
- TMC1 | c.-84T>A | 5'UTR (SNP) | VAF 65/338 reads (19%) | called by muse, mutect2, varscan2
- TP73 | c.-1G>A | 5'UTR (SNP) | VAF 7/34 reads (21%) | catalogued as rs770515574; called by muse, mutect2, varscan2
- UQCRB | c.*2275G>T | 3'UTR (SNP) | VAF 50/345 reads (14%) | called by muse, mutect2, varscan2
- USP17L30 | chr4:9369026 G>T | 3'Flank (SNP) | VAF 51/1328 reads (4%) | catalogued as rs774217939; called by muse, mutect2
